Somatic mutation profile of tumor specimen TCGA-LK-A4NY-01A (aliquot TCGA-LK-A4NY-01A-11D-A34C-32) from TCGA case TCGA-LK-A4NY, project TCGA-MESO (Mesothelioma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Mesothelioma, biphasic, malignant; Tissue or organ of origin: Pleura, NOS; AJCC pathologic stage: Stage III; Age at diagnosis: 66.8 years (24,391 days).
Specimen TCGA-LK-A4NY-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0c79c65a-d08e-4583-9b51-d9bef6d1b98c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-LK-A4NY-10A (Blood Derived Normal), aliquot TCGA-LK-A4NY-10A-01D-A34C-32; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8ad2ac15-1ef2-403c-a4b0-4cb750e0b7ba

The open-access MAF lists 48 somatic variants for this specimen: 38 protein-altering or splice-affecting, 9 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 30, Silent 9, Splice Site 4, Nonsense Mutation 2, Frame Shift Del 2, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACOT11 | c.291C>G p.I97M | Missense Mutation (SNP) | VAF 58/177 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); catalogued as COSV59351565; called by muse, mutect2, varscan2
- AFAP1L1 | c.1480G>C p.A494P | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57046957; called by muse, mutect2, varscan2
- ARMC3 | c.1346G>A p.R449H | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs199547387, COSV53058095; called by muse, mutect2, varscan2
- CD5 | c.1006A>G p.T336A | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as rs751748072; called by muse, mutect2, varscan2
- CLINT1 | c.736C>T p.P246S | Missense Mutation (SNP) | VAF 45/117 reads (38%) | SIFT tolerated (0.77); PolyPhen benign (0.035); catalogued as COSV51629426; called by muse, mutect2, varscan2
- FSIP2 | c.19714G>A p.A6572T | Missense Mutation (SNP) | VAF 47/120 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); catalogued as COSV58093121; called by muse, mutect2, varscan2
- IQSEC1 | c.2810G>A p.R937H | Missense Mutation (SNP) | VAF 32/91 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.886); catalogued as rs1354797446; called by muse, mutect2, varscan2
- MUC17 | c.9262A>G p.T3088A | Missense Mutation (SNP) | VAF 115/327 reads (35%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.636); catalogued as rs1562816293; called by muse, mutect2, varscan2
- NCOA7 | c.1219G>A p.E407K | Missense Mutation (SNP) | VAF 12/172 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.551); catalogued as rs1484386629; called by muse, mutect2
- PAX5 | c.1169G>A p.R390H | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated, low confidence (0.28); PolyPhen probably damaging (0.991); catalogued as rs771002648, COSV63908373; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- POLR2G | c.371A>G p.N124S | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs570529425; called by muse, mutect2, varscan2
- TMEM132A | c.2980G>A p.E994K (on ENST00000453848 / NM_178031.3; = p.E995K on NM_017870.4) | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs878967572; called by muse, mutect2, varscan2
- TMEM37 | c.526G>A p.A176T | Missense Mutation (SNP) | VAF 25/96 reads (26%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.845); catalogued as rs561884988, COSV50026848; called by muse, mutect2, varscan2
- ABCC2 | c.1530+6_1530+13del p.X510_splice | Splice Site (DEL) | VAF 6/62 reads (10%) | called by mutect2, pindel
- ABCG8 | c.329G>A p.G110E | Missense Mutation (SNP) | VAF 33/93 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADAMTS9 | c.5522-1G>A p.X1841_splice | Splice Site (SNP) | VAF 18/56 reads (32%) | called by muse, mutect2, varscan2
- AGBL1 | c.1978_1987+16del p.X660_splice | Splice Site (DEL) | VAF 7/54 reads (13%) | called by mutect2, pindel
- AGO1 | c.1643A>C p.K548T | Missense Mutation (SNP) | VAF 28/92 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- ARHGAP29 | c.2902A>T p.S968C | Missense Mutation (SNP) | VAF 36/67 reads (54%) | SIFT tolerated (0.2); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- DACH1 | c.886G>C p.V296L | Missense Mutation (SNP) | VAF 53/134 reads (40%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- EPHB2 | c.1186A>T p.S396C | Missense Mutation (SNP) | VAF 85/220 reads (39%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- GEM | c.122_137del p.S41Ifs*36 | Frame Shift Del (DEL) | VAF 12/46 reads (26%) | called by mutect2, varscan2
- IL23R | c.975A>T p.K325N | Missense Mutation (SNP) | VAF 59/181 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- LAMA5 | c.1322A>G p.E441G | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MCF2L2 | c.467_486+1del p.X156_splice | Splice Site (DEL) | VAF 32/163 reads (20%) | called by mutect2, pindel, varscan2
- MGA | c.8920G>A p.E2974K (on ENST00000219905 / NM_001164273.1; = p.E2765K on NM_001080541.2) | Missense Mutation (SNP) | VAF 33/58 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.612); called by muse, mutect2, varscan2
- MYBL1 | c.182T>C p.I61T | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- NKTR | c.4056C>A p.S1352R | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PLXNA1 | c.5606C>A p.A1869D | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.603); called by muse, mutect2, varscan2
- PSMB5 | c.757G>A p.D253N | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- RNF19A | c.557A>G p.H186R | Missense Mutation (SNP) | VAF 56/158 reads (35%) | SIFT tolerated (0.2); PolyPhen benign (0.143); called by muse, mutect2, varscan2
- ROS1 | c.5692G>T p.V1898L | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- SLC4A9 | c.1199A>T p.Y400F (on ENST00000507527 / NM_001258428.2; = p.Y376F on NM_031467.3) | Missense Mutation (SNP) | VAF 57/159 reads (36%) | SIFT tolerated (0.65); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TBL3 | c.219C>A p.D73E | Missense Mutation (SNP) | VAF 51/133 reads (38%) | SIFT tolerated (0.41); PolyPhen benign (0); called by muse, mutect2, varscan2
- TBX3 | c.328A>T p.K110* | Nonsense Mutation (SNP) | VAF 21/60 reads (35%) | called by muse, mutect2, varscan2
- TM9SF2 | c.1665_1671del p.G556Yfs*47 | Frame Shift Del (DEL) | VAF 6/37 reads (16%) | called by mutect2, pindel, varscan2
- TTLL12 | c.1770C>A p.D590E | Missense Mutation (SNP) | VAF 21/35 reads (60%) | SIFT tolerated (0.4); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- USP24 | c.3445C>T p.Q1149* | Nonsense Mutation (SNP) | VAF 69/191 reads (36%) | called by muse, mutect2, varscan2
- ASXL1 | c.4290C>G p.L1430= | Silent (SNP) | VAF 65/191 reads (34%) | catalogued as rs745543812; called by muse, mutect2, varscan2
- CILP2 | c.3078C>G p.L1026= | Silent (SNP) | VAF 9/129 reads (7%) | called by muse, mutect2
- FBXW5 | c.837C>A p.I279= | Silent (SNP) | VAF 20/45 reads (44%) | called by muse, mutect2, varscan2
- PNMT | c.768T>C p.Y256= | Silent (SNP) | VAF 9/33 reads (27%) | called by muse, mutect2, varscan2
- RTN4RL1 | c.225C>T p.S75= | Silent (SNP) | VAF 9/126 reads (7%) | called by muse, mutect2
- SEMA6B | c.2187C>T p.A729= | Silent (SNP) | VAF 10/25 reads (40%) | called by muse, mutect2, varscan2
- TEX15 | c.4401G>A p.A1467= (on ENST00000256246; = p.A1850= on NM_001350162.2) | Silent (SNP) | VAF 14/39 reads (36%) | catalogued as rs746702451, COSV99821825, COSV99822248; called by muse, mutect2, varscan2
- TNFRSF19 | c.219G>A p.V73= | Silent (SNP) | VAF 10/32 reads (31%) | called by muse, mutect2, varscan2
- ZNF333 | c.1347C>G p.P449= | Silent (SNP) | VAF 30/96 reads (31%) | catalogued as COSV99468675; called by muse, mutect2, varscan2
- SLCO2A1 | chr3:133928595 C>A | 3'Flank (SNP) | VAF 18/49 reads (37%) | called by muse, mutect2, varscan2
